Somatic mutation profile of tumor specimen TCGA-DK-A3X1-01A (aliquot TCGA-DK-A3X1-01A-12D-A22Z-08) from TCGA case TCGA-DK-A3X1, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 78.7 years (28,757 days).
Specimen TCGA-DK-A3X1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de1b0f6a-8a93-4cb9-a0bf-2b62efe7d279.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A3X1-10A (Blood Derived Normal), aliquot TCGA-DK-A3X1-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/153791ec-36af-488d-9e7a-43b74133c8cf

The open-access MAF lists 977 somatic variants for this specimen: 690 protein-altering or splice-affecting, 265 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 593, Silent 265, Nonsense Mutation 75, Intron 9, Splice Site 8, 3'UTR 6, Splice Region 5, Nonstop Mutation 3, RNA 3, 5'Flank 3, Translation Start Site 3, Frame Shift Del 2.

Variants (750 of 977; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 13/98 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 17/34 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060501191, COSV52666332, COSV52700326, COSV52746468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA1 | c.4639C>G p.P1547A | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV66068516, COSV66070239; called by muse, mutect2, varscan2
- ABCA4 | c.4129-1G>C p.X1377_splice | Splice Site (SNP) | VAF 9/34 reads (26%) | catalogued as COSV64675575; called by muse, mutect2, varscan2
- ABCA9 | c.1606C>G p.P536A | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); catalogued as rs776664778, COSV60628215; called by muse, mutect2, varscan2
- ABCC1 | c.345C>G p.I115M | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.344); catalogued as COSV60689916; called by muse, mutect2, varscan2
- ABCD2 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58051835; called by muse, mutect2, varscan2
- AC068580.4 | c.910C>G p.P304A | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV52589162, COSV99362420; called by muse, mutect2, varscan2
- AC092143.1 | c.1941G>A p.M647I | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as COSV59248328; called by muse, mutect2, varscan2
- AC244197.3 | c.287T>C p.L96S | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV61713180; called by muse, mutect2, varscan2
- ACAD9 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1484341169, COSV58308846; called by muse, mutect2, varscan2
- ACAN | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs372286756, COSV61358491; called by muse, mutect2, varscan2
- ACOT2 | c.85C>G p.R29G | Missense Mutation (SNP) | VAF 65/124 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.528); catalogued as COSV53150929; called by muse, mutect2, varscan2
- ACSF2 | c.967C>G p.L323V | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs539511131, COSV51973445; called by muse, mutect2, varscan2
- ADAMTS12 | c.956C>G p.S319C | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV61270333; called by muse, varscan2
- ADAMTS12 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV61270343; called by muse, varscan2
- ADAMTS3 | c.1688G>C p.C563S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54396868; called by muse, mutect2, varscan2
- ADAMTSL1 | c.913G>C p.D305H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52820134, COSV99441645; called by muse, mutect2, varscan2
- ADARB1 | c.1279C>G p.Q427E | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760565860, COSV62346080; called by muse, mutect2, varscan2
- ADCK2 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1436624517, COSV50782380; called by muse, mutect2, varscan2
- ADCY10 | c.2474C>T p.S825F | Missense Mutation (SNP) | VAF 35/336 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV63242870; called by muse, mutect2, varscan2
- ADGRA1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs982470636, COSV66926501; called by muse, mutect2, varscan2
- ADGRE2 | c.740G>T p.R247I | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100216343; called by muse, mutect2, varscan2
- ADH1B | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 88/593 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs75973598, COSV59297627; called by muse, mutect2, varscan2
- ADM | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53403491; called by muse, mutect2, varscan2
- AFAP1L1 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV57046545; called by muse, mutect2, varscan2
- AFF2 | c.1089G>A p.E363= | Splice Region (SNP) | VAF 6/74 reads (8%) | catalogued as COSV53998504; called by muse, mutect2
- AHR | c.817C>A p.Q273K | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV54124881; called by muse, mutect2, varscan2
- AKR1E2 | c.385C>G p.R129G | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748631440, COSV53629928; called by muse, mutect2, varscan2
- ALDOA | c.319G>A p.E107K (on ENST00000642816 / NM_001243177.4; = p.E53K on NM_184041.5) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV57633346; called by muse, mutect2, varscan2
- ALOX15 | c.1760C>G p.S587C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.125); catalogued as COSV53399298; called by muse, mutect2, varscan2
- AMER2 | c.1494C>G p.I498M | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as COSV63438927; called by muse, mutect2, varscan2
- AMHR2 | c.1693C>T p.Q565* | Nonsense Mutation (SNP) | VAF 35/84 reads (42%) | catalogued as rs776513024; called by muse, mutect2, varscan2
- ANKRD26 | c.3839C>G p.A1280G | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV65776790; called by muse, mutect2, varscan2
- ANO3 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV56799984; called by muse, mutect2, varscan2
- ANO4 | c.1267G>A p.D423N (on ENST00000392977 / NM_001286615.2; = p.D388N on NM_178826.4) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54604937; called by muse, mutect2, varscan2
- AP2B1 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 40/289 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52001343; called by muse, mutect2, varscan2
- APOL5 | c.1100G>C p.R367P | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.308); catalogued as COSV50767713; called by muse, mutect2, varscan2
- AQP11 | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1184154429, COSV57992818; called by muse, mutect2, varscan2
- ARAP2 | c.3753G>C p.Q1251H | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as COSV58289488; called by muse, mutect2, varscan2
- ARHGAP20 | c.3541G>A p.D1181N | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs148304862; called by muse, mutect2, varscan2
- ARHGAP35 | c.1645C>G p.H549D | Missense Mutation (SNP) | VAF 83/201 reads (41%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.583); catalogued as COSV68333442; called by muse, mutect2, varscan2
- ARHGEF1 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs781882065, COSV61528759; called by muse, mutect2, varscan2
- ARHGEF16 | c.1517G>C p.G506A | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65682593; called by muse, mutect2, varscan2
- ARHGEF5 | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV99282810; called by muse, mutect2, varscan2
- ARID1B | c.6145G>T p.E2049* | Nonsense Mutation (SNP) | VAF 43/156 reads (28%) | catalogued as rs1554237958, COSV51647084, COSV99268939; called by muse, mutect2, varscan2
- ARMC9 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201558091, COSV63022368; called by muse, mutect2, varscan2
- ARSF | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.516); catalogued as COSV63840369; called by muse, mutect2, varscan2
- ARSH | c.960C>A p.F320L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV66963521; called by muse, mutect2, varscan2
- ASF1B | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs752464241, COSV54616549; called by muse, varscan2
- ASXL1 | c.3269G>C p.R1090T | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV60114452; called by muse, mutect2, varscan2
- ATG2B | c.2285G>A p.R762Q | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs755801235, COSV63424481; called by muse, mutect2, varscan2
- ATP12A | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 39/324 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.78); catalogued as COSV54519637, COSV54524667; called by muse, mutect2, varscan2
- ATP13A5 | c.2212C>T p.P738S | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV60868709; called by muse, mutect2, varscan2
- ATP6AP2 | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.452); catalogued as COSV65798061; called by muse, mutect2, varscan2
- ATP8B1 | c.1783G>C p.D595H | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52178169; called by muse, mutect2, varscan2
- ATXN1 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs924615813, COSV55223189; called by muse, mutect2
- BEND7 | c.561G>C p.E187D | Missense Mutation (SNP) | VAF 27/239 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.074); catalogued as COSV61990076; called by muse, mutect2, varscan2
- BHLHE40 | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as COSV56576006; called by muse, mutect2, varscan2
- BOC | c.2476C>G p.L826V | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV56354880; called by muse, mutect2, varscan2
- BOLA1 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | catalogued as COSV64967392; called by muse, mutect2, varscan2
- BRIP1 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 45/435 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV52004097; called by muse, mutect2, varscan2
- BRWD3 | c.5316G>C p.E1772D | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); catalogued as COSV64751334; called by muse, mutect2, varscan2
- BSX | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV58005338; called by muse, mutect2, varscan2
- BTN1A1 | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 103/312 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV55068652; called by muse, mutect2, varscan2
- C10orf90 | c.247C>A p.H83N | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.341); catalogued as COSV52959207; called by muse, mutect2, varscan2
- C12orf43 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs1176572996, COSV56566313, COSV56566816; called by muse, mutect2, varscan2
- C1QTNF9 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV100130007, COSV59657665; called by muse, mutect2, varscan2
- C1orf127 | c.1900A>G p.R634G | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.169); catalogued as COSV65438064; called by muse, mutect2, varscan2
- C3orf18 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.205); catalogued as COSV51751420; called by muse, mutect2, varscan2
- C3orf62 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.371); catalogued as COSV55536878; called by muse, mutect2, varscan2
- CACNA1C | c.6242G>T p.R2081I (on ENST00000399634 / NM_001167625.1; = p.R2010I on NM_000719.7) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.206); catalogued as rs754647829, COSV59704658, COSV59711382; called by muse, mutect2, varscan2
- CACNA1H | c.6593C>T p.A2198V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs776473889, COSV52356100; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNB2 | c.292G>C p.E98Q (on ENST00000324631 / NM_201596.3; = p.E43Q on NM_000724.4) | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56636606; called by muse, mutect2
- CADPS | c.3902G>A p.R1301Q | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs755694732, COSV51891724, COSV99340302; called by muse, mutect2, varscan2
- CALHM2 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs763215247, COSV53296969; called by muse, mutect2, varscan2
- CAMKK2 | c.415C>G p.R139G | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61216310; called by muse, mutect2
- CAMSAP2 | c.3433G>A p.D1145N (on ENST00000236925 / NM_001297707.2; = p.D1134N on NM_203459.3) | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV52674104; called by muse, mutect2, varscan2
- CARMIL1 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV61518971; called by muse, mutect2, varscan2
- CASQ2 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs769435706, COSV54772325; called by muse, mutect2, varscan2
- CBL | c.1310G>T p.R437I | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV50648122; called by muse, mutect2, varscan2
- CBL | c.1407G>A p.M469I | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV50645597; called by muse, mutect2, varscan2
- CCDC180 | c.103A>C p.K35Q | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as COSV63832718; called by muse, mutect2, varscan2
- CCDC34 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58726513; called by muse, mutect2, varscan2
- CCL13 | c.240G>C p.K80N | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.501); catalogued as COSV56775072; called by muse, mutect2, varscan2
- CCNB1 | c.1267G>C p.V423L | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV56510598; called by muse, mutect2, varscan2
- CCNE2 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 82/233 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57376868; called by muse, mutect2, varscan2
- CD101 | c.2063C>A p.S688Y | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV56719432; called by muse, mutect2, varscan2
- CD109 | c.1902G>C p.Q634H | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV54653262; called by muse, mutect2, varscan2
- CD1B | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 15/269 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV63804746; called by muse, mutect2
- CD46 | c.891G>C p.L297F | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.049); catalogued as COSV59734387; called by muse, mutect2, varscan2
- CDC5L | c.845C>T p.T282I | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV65176682; called by muse, mutect2, varscan2
- CDH19 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as COSV50966779; called by muse, mutect2, varscan2
- CDK15 | c.836C>G p.S279C (on ENST00000652192 / NM_001366386.2; = p.S228C on NM_139158.2) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV53636279; called by muse, mutect2, varscan2
- CDK18 | c.18G>T p.M6I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.076); catalogued as COSV63728279; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4174C>G p.Q1392E | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV62576377; called by muse, mutect2, varscan2
- CDS1 | c.789T>G p.F263L | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as rs776261160, COSV55686412, COSV55689171; called by muse, mutect2, varscan2
- CEL | c.2245C>T p.Q749* (on ENST00000673714; = p.Q746* on NM_001807.6) | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as COSV60830154; called by muse, mutect2, varscan2
- CENPF | c.1684G>C p.D562H | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV65276916; called by muse, mutect2, varscan2
- CEP192 | c.6173C>T p.S2058L | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV58066744; called by muse, mutect2, varscan2
- CEP350 | c.2330C>G p.S777C | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV62606454; called by muse, mutect2
- CEP350 | c.2923C>G p.L975V | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV62606465, COSV62610469; called by muse, mutect2, varscan2
- CEP55 | c.502C>G p.H168D | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV65185485; called by muse, mutect2, varscan2
- CEP97 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.155); catalogued as COSV59126079; called by muse, mutect2, varscan2
- CHD8 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 11/18 reads (61%) | catalogued as rs1555318635, COSV101303026; called by muse, mutect2, varscan2
- CHD9 | c.3979G>A p.D1327N | Missense Mutation (SNP) | VAF 36/316 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54607912, COSV54613414; called by muse, mutect2, varscan2
- CHRND | c.1050C>G p.L350= | Splice Region (SNP) | VAF 19/91 reads (21%) | catalogued as COSV51324771; called by muse, mutect2, varscan2
- CHRND | c.1347G>A p.M449I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV51324852, COSV99033262; called by muse, mutect2, varscan2
- CIART | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as COSV51745221; called by muse, mutect2, varscan2
- CLASP1 | c.3132G>T p.Q1044H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55331383; called by muse, mutect2, varscan2
- CLEC16A | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs1376995439, COSV68500918; called by muse, mutect2, varscan2
- CLTB | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.218); catalogued as COSV60044282, COSV60045090; called by muse, mutect2, varscan2
- CNOT1 | c.2232C>G p.F744L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV57775446; called by muse, mutect2, varscan2
- CNTN1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV61642570; called by muse, mutect2, varscan2
- CNTN5 | c.690G>T p.W230C | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54334070; called by muse, varscan2
- COL11A1 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.055); catalogued as COSV62190039; called by muse, mutect2, varscan2
- COL14A1 | c.2486C>T p.S829F | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV52861676; called by muse, mutect2
- COL4A2 | c.4229G>A p.R1410Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.19); catalogued as rs1004346642, COSV64629756; called by muse, mutect2, varscan2
- COL6A3 | c.3869C>G p.S1290C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV55099001; called by mutect2, varscan2
- CROT | c.877-1G>A p.X293_splice | Splice Site (SNP) | VAF 9/29 reads (31%) | catalogued as rs759136795, COSV58975737; called by muse, mutect2, varscan2
- CSMD2 | c.8129G>C p.R2710P | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV53912582, COSV53935681; called by muse, mutect2, varscan2
- CTCF | c.2059G>T p.E687* | Nonsense Mutation (SNP) | VAF 8/77 reads (10%) | catalogued as COSV50486390; called by muse, mutect2, varscan2
- CUL4A | c.619G>A p.E207K (on ENST00000375440 / NM_001008895.4; = p.E107K on NM_003589.3) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as rs746392573, COSV58374420; called by muse, mutect2, varscan2
- CUL5 | c.1195C>G p.Q399E | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs773488535, COSV63230137; called by muse, mutect2, varscan2
- CYLC2 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.907); catalogued as COSV66337669; called by muse, mutect2, varscan2
- CYP2A13 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs148044792, CM067778, COSV57836963; called by muse, mutect2, varscan2
- CYP4B1 | c.1468C>T p.L490F | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.445); catalogued as COSV54724812; called by muse, mutect2, varscan2
- DAB2IP | c.460G>C p.E154Q (on ENST00000408936; = p.E126Q on NM_032552.3) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV52263963; called by muse, mutect2, varscan2
- DAPK1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.353); catalogued as COSV63789647; called by muse, mutect2, varscan2
- DBF4 | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.057); catalogued as COSV55997992; called by muse, mutect2, varscan2
- DCC | c.1982G>A p.R661Q | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs375859461; called by muse, mutect2, varscan2
- DCSTAMP | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV52577569; called by muse, varscan2
- DDX27 | c.2214G>C p.K738N | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.074); catalogued as COSV65599641; called by muse, mutect2, varscan2
- DDX42 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as COSV63790710; called by muse, mutect2, varscan2
- DDX50 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.115); catalogued as COSV65292943; called by muse, mutect2, varscan2
- DDX51 | c.1638G>A p.M546I | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV57959100; called by muse, mutect2, varscan2
- DEPDC1 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV63958650; called by muse, mutect2, varscan2
- DGKA | c.2190C>A p.F730L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs1343685122, COSV59385441; called by muse, mutect2, varscan2
- DHX16 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV64564779; called by muse, mutect2, varscan2
- DIDO1 | c.4324G>C p.D1442H | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV56628815; called by muse, mutect2, varscan2
- DLC1 | c.4150C>T p.R1384C (on ENST00000276297 / NM_001348081.2; = p.R947C on NM_006094.5) | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs778397065, COSV52298302; called by muse, mutect2, varscan2
- DLEC1 | c.2685G>A p.M895I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV57303080; called by muse, mutect2, varscan2
- DLST | c.549G>C p.Q183H | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV53167047; called by muse, mutect2, varscan2
- DMTN | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs867678554, COSV56113538; called by muse, mutect2, varscan2
- DNAH3 | c.9198C>G p.I3066M | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV54536401; called by muse, mutect2, varscan2
- DNAH3 | c.7091G>A p.G2364E | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1432005571, COSV54536419; called by muse, mutect2
- DNAH7 | c.2167C>G p.Q723E | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs747904123, COSV56762585; called by muse, mutect2, varscan2
- DNAJA3 | c.1337C>G p.S446C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV52163177; called by muse, mutect2, varscan2
- DNAJC10 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV51142497; called by muse, mutect2, varscan2
- DOCK10 | c.5521G>C p.E1841Q | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV51421433; called by muse, mutect2, varscan2
- DOCK11 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as COSV52243847; called by muse, mutect2, varscan2
- DOCK7 | c.3308C>T p.S1103L (on ENST00000635253 / NM_001367561.1; = p.S1072L on NM_033407.3) | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV52014076; called by muse, mutect2, varscan2
- DOP1A | c.2273C>G p.S758* | Nonsense Mutation (SNP) | VAF 36/99 reads (36%) | catalogued as COSV52718206, COSV99380569; called by muse, mutect2, varscan2
- DPY19L4 | c.1450G>C p.E484Q | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.783); catalogued as COSV68963400; called by muse, mutect2, varscan2
- DUSP16 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.91); PolyPhen benign (0.096); catalogued as COSV53808778; called by muse, mutect2, varscan2
- DUSP29 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as rs757109253, COSV58301132; called by muse, mutect2, varscan2
- DVL3 | c.817G>T p.D273Y | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57457263; called by muse, mutect2, varscan2
- DYNC2I1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as COSV68106013, COSV68107751; called by muse, mutect2
- EAF1 | c.584C>G p.S195C | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV67657214, COSV67657344; called by muse, varscan2
- EAF1 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 69/108 reads (64%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV67657347; called by muse, varscan2
- ECT2L | c.1231C>G p.Q411E | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.192); catalogued as COSV62885950; called by muse, mutect2, varscan2
- EGFL6 | c.870G>T p.M290I | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV63634551; called by muse, mutect2, varscan2
- EHBP1L1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV58574117; called by muse, mutect2, varscan2
- EIF2B2 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.916); catalogued as COSV56720976; called by muse, mutect2, varscan2
- EIF2B2 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 52/358 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56720989; called by muse, varscan2
- EIF2S3 | c.1003G>A p.G335S | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.641); catalogued as COSV53406596; called by muse, mutect2, varscan2
- EIF3J | c.458G>C p.R153T | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV56009350; called by muse, mutect2, varscan2
- EMILIN3 | c.2047C>G p.Q683E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV60037474; called by muse, mutect2, varscan2
- EPB41L4B | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65797892; called by muse, mutect2, varscan2
- EPHA2 | c.1938G>C p.K646N | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV64454017; called by muse, mutect2
- EPHX3 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750393630, COSV55656111; called by muse, mutect2, varscan2
- EPN3 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.855); catalogued as rs1183852974, COSV52141514; called by muse, mutect2, varscan2
- EPX | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 69/228 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.242); catalogued as rs375820407, COSV56598004; called by muse, mutect2, varscan2
- ERAP2 | c.133C>T p.H45Y | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV65940669; called by muse, mutect2, varscan2
- ERCC3 | c.2033G>A p.R678K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV53428499; called by muse, mutect2, varscan2
- ERICH3 | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 59/180 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs867745110, COSV58603843; called by muse, mutect2, varscan2
- ERRFI1 | c.715C>G p.P239A | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV66310939; called by muse, mutect2, varscan2
- EVX1 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV56085753; called by muse, mutect2, varscan2
- EXOC4 | c.62C>A p.S21* | Nonsense Mutation (SNP) | VAF 12/74 reads (16%) | catalogued as rs183280115, COSV54081769, COSV99555488; called by muse, mutect2, varscan2
- EXOC8 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV50478825; called by muse, mutect2, varscan2
- EXPH5 | c.4669G>C p.D1557H | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV56205299; called by muse, mutect2, varscan2
- FADS2 | c.753G>C p.K251N | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.574); catalogued as COSV53897170, COSV53900615; called by muse, mutect2, varscan2
- FADS3 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV53879467; called by muse, mutect2, varscan2
- FAM102A | c.1115C>G p.S372C (on ENST00000373095 / NM_001035254.3; = p.S230C on NM_203305.2) | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as COSV55948526; called by muse, mutect2, varscan2
- FAM131A | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 82/274 reads (30%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.003); catalogued as COSV55602506; called by muse, mutect2, varscan2
- FAM166C | c.437A>T p.E146V | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as COSV56602250; called by muse, mutect2, varscan2
- FASN | c.6022G>A p.E2008K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.012); catalogued as COSV60758005; called by muse, mutect2, varscan2
- FAT2 | c.10921G>A p.E3641K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs776662495, COSV55812696; called by muse, mutect2, varscan2
- FAT4 | c.7244C>T p.S2415L | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as rs767319999, COSV58682799; called by muse, mutect2, varscan2
- FBLN2 | c.2602C>T p.R868C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs372540399; called by muse, mutect2, varscan2
- FBN1 | c.2122C>G p.Q708E | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as CM095636, COSV57324083; called by muse, mutect2, varscan2
- FBXL18 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs778622022, COSV101212040, COSV66667698; called by muse, mutect2, varscan2
- FBXO32 | c.934G>C p.D312H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV54891740; called by muse, mutect2, varscan2
- FBXO41 | c.2394G>T p.E798D | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV54581480; called by muse, mutect2
- FBXO42 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as rs1306328789, COSV65046364; called by muse, mutect2, varscan2
- FCHO1 | c.2245C>G p.Q749E | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV53183737; called by muse, mutect2, varscan2
- FCRL2 | c.794T>C p.V265A | Missense Mutation (SNP) | VAF 60/321 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.838); catalogued as COSV63834366; called by muse, mutect2, varscan2
- FGFBP2 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.772); catalogued as COSV52588315; called by muse, mutect2, varscan2
- FLACC1 | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51855272; called by muse, mutect2, varscan2
- FLG | c.7473T>G p.H2491Q | Missense Mutation (SNP) | VAF 194/833 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV64244951; called by muse, mutect2
- FMNL3 | c.1248G>C p.E416D | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV53305059; called by muse, mutect2, varscan2
- FOXD4L3 | c.983G>C p.R328T | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs782029419; called by muse, mutect2, varscan2
- FOXQ1 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57258702, COSV99723361; called by muse, mutect2, varscan2
- FREM2 | c.7232A>G p.Y2411C | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54844616; called by muse, mutect2, varscan2
- FRY | c.6175G>C p.E2059Q | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66574452; called by muse, mutect2, varscan2
- GALT | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV66593258; called by muse, mutect2, varscan2
- GANAB | c.386C>G p.S129C | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV60466806; called by muse, mutect2, varscan2
- GAPDHS | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs771529008, COSV55882305; called by muse, mutect2, varscan2
- GASK1B | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV56709593; called by muse, mutect2, varscan2
- GDPD2 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV65533669; called by muse, mutect2, varscan2
- GIMAP2 | c.605T>C p.I202T | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as rs138926685; called by muse, mutect2, varscan2
- GLDC | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs1563852496, COSV58678315, COSV58682679; called by muse, mutect2, varscan2
- GLRA3 | c.297G>C p.Q99H | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56866093; called by muse, mutect2, varscan2
- GLRB | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.044); catalogued as COSV52417119; called by muse, mutect2, varscan2
- GMPPB | c.982G>A p.E328K (on ENST00000308388 / NM_021971.4; = p.E355K on NM_013334.3) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1356812347, COSV100246465, COSV57539377; called by muse, mutect2, varscan2
- GNB3 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV57529689; called by muse, mutect2, varscan2
- GPN1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV53116226; called by muse, mutect2, varscan2
- GRHL1 | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61215675; called by muse, mutect2
- GRIA2 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.424); catalogued as COSV52398270; called by muse, mutect2, varscan2
- GRIK2 | c.2323C>G p.R775G | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100022709, COSV59753542; called by muse, mutect2, varscan2
- GRIN3A | c.1633G>C p.D545H | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV62453691, COSV62456244; called by muse, mutect2, varscan2
- GRIPAP1 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV64552726; called by muse, mutect2, varscan2
- GRIPAP1 | c.1774-1G>T p.X592_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as COSV64552739; called by muse, mutect2, varscan2
- GSC | c.696G>A p.W232* | Nonsense Mutation (SNP) | VAF 29/222 reads (13%) | catalogued as rs1300142965; called by muse, mutect2, varscan2
- GSG1 | c.828C>G p.F276L (on ENST00000651961 / NM_001080555.4; = p.Q282E on NM_031289.5) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV52193967, COSV52196020; called by muse, mutect2
- GSS | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs373345937; called by muse, mutect2, varscan2
- HAT1 | c.607C>G p.L203V | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as rs766247676, COSV51364258; called by muse, mutect2, varscan2
- HAT1 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140409528; called by muse, mutect2, varscan2
- HCRTR2 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV63797454; called by muse, mutect2, varscan2
- HDAC9 | c.2130G>T p.Q710H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV67779411; called by muse, mutect2
- HDHD3 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as COSV53057785, COSV99445001; called by muse, mutect2, varscan2
- HDLBP | c.2761G>C p.E921Q | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.087); catalogued as rs770822941, COSV60498938; called by muse, mutect2, varscan2
- HERC2 | c.986C>G p.S329C | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.62); catalogued as rs763039737, COSV55319066, COSV55332717; called by muse, mutect2
- HEXD | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV57342092; called by muse, mutect2, varscan2
- HMCN1 | c.16333G>A p.E5445K | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as rs1239193190, COSV54919750; called by muse, mutect2, varscan2
- HMGCR | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 84/173 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55317049; called by muse, mutect2, varscan2
- HNRNPK | c.773G>C p.R258T | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.136); catalogued as COSV61090295; called by muse, mutect2, varscan2
- HORMAD1 | c.940C>G p.H314D | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100464446; called by muse, mutect2, varscan2
- HOXC8 | c.177C>G p.F59L | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.952); catalogued as COSV50002295; called by muse, mutect2, varscan2
- HROB | c.1891G>C p.D631H | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55370286; called by muse, mutect2, varscan2
- HSF4 | c.773G>A p.R258K (on ENST00000521374 / NM_001040667.3; = p.G263R on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV50458341; called by muse, mutect2, varscan2
- HSPD1 | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61445297; called by muse, mutect2, varscan2
- HYDIN | c.14752G>A p.E4918K | Missense Mutation (SNP) | VAF 142/519 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs1234140620, COSV66640478; called by muse, varscan2
- HYDIN | c.14698G>A p.E4900K | Missense Mutation (SNP) | VAF 124/424 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1288664003, COSV66640483; called by muse, varscan2
- IGDCC4 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61536696, COSV61538238; called by muse, mutect2, varscan2
- IGF2R | c.7068G>A p.V2356= | Splice Region (SNP) | VAF 9/51 reads (18%) | catalogued as COSV63630959; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 42/624 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as rs763305595; called by muse, mutect2
- IGKV2-30 | c.63T>G p.D21E | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.076); catalogued as rs573614892; called by mutect2, varscan2
- IL10RA | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.731); catalogued as COSV57141458; called by muse, mutect2, varscan2
- IL17A | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 99/249 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs1285825975, COSV60685074; called by muse, mutect2, varscan2
- IL18RAP | c.1760C>G p.T587R | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as COSV51827627; called by muse, mutect2, varscan2
- IL21R | c.691A>G p.K231E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV61971537; called by muse, mutect2, varscan2
- INPP5D | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.376); catalogued as COSV64038687; called by muse, mutect2, varscan2
- IRF4 | c.958G>C p.A320P | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV66705378, COSV66705721; called by muse, mutect2, varscan2
- IRS1 | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs544750977, COSV59333635; called by muse, mutect2, varscan2
- ITGA9 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV53249815; called by muse, mutect2, varscan2
- ITM2A | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV64811399; called by muse, mutect2, varscan2
- ITPR2 | c.4736G>T p.R1579I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV67272817; called by muse, mutect2, varscan2
- JMJD1C | c.7111G>A p.D2371N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV59516780; called by muse, mutect2, varscan2
- JRKL | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.259); catalogued as COSV53594449; called by muse, mutect2, varscan2
- KANK1 | c.2260G>A p.V754M | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.569); catalogued as rs766484676, COSV63213886; called by muse, mutect2, varscan2
- KATNB1 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV65551913; called by muse, mutect2, varscan2
- KCNS2 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 50/283 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs373045610; called by muse, mutect2, varscan2
- KDR | c.2915C>T p.S972L | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.039); catalogued as COSV55771057; called by muse, mutect2, varscan2
- KDR | c.2159G>A p.R720Q | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs375909858; called by muse, mutect2, varscan2
- KHDRBS2 | c.1013G>C p.R338T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV55468987, COSV55473063; called by muse, mutect2, varscan2
- KIAA0100 | c.4621G>A p.E1541K | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV66494965; called by muse, mutect2, varscan2
- KIAA1109 | c.1210G>C p.E404Q | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52683311; called by muse, mutect2, varscan2
- KIF13A | c.3229G>C p.D1077H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.601); catalogued as COSV52458650; called by muse, mutect2, varscan2
- KIF13A | c.401C>G p.S134C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); catalogued as COSV52458677; called by muse, mutect2, varscan2
- KIF14 | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV66259819, COSV66262318; called by muse, varscan2
- KIF14 | c.470C>G p.S157C | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV66262825; called by muse, varscan2
- KIF21A | c.2500C>T p.R834C (on ENST00000361418 / NM_001378440.1; = p.R821C on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs762662150, COSV62771565; called by muse, mutect2, varscan2
- KIT | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as COSV55411449; called by muse, mutect2, varscan2
- KL | c.949C>G p.Q317E | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV66309427; called by muse, mutect2, varscan2
- KLB | c.3120G>C p.K1040N | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs759313925, COSV57303299; called by muse, mutect2, varscan2
- KLF5 | c.279G>C p.E93D | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66614992; called by muse, mutect2, varscan2
- KLHL32 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1236752449, COSV65113332; called by muse, mutect2
- KMT2A | c.8518G>A p.D2840N | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100629959, COSV63289708; called by muse, mutect2, varscan2
- KMT2A | c.11254G>T p.E3752* | Nonsense Mutation (SNP) | VAF 16/131 reads (12%) | catalogued as COSV100628760; called by muse, varscan2
- KMT2D | c.15508C>T p.Q5170* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as COSV56431224; called by mutect2, varscan2
- KNL1 | c.704C>T p.S235L (on ENST00000346991 / NM_170589.5; = p.S209L on NM_144508.5) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV61157727; called by muse, mutect2, varscan2
- LAMA1 | c.3690C>G p.L1230= | Splice Region (SNP) | VAF 31/114 reads (27%) | catalogued as COSV67540418; called by muse, mutect2, varscan2
- LAMB1 | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55967614; called by muse, mutect2, varscan2
- LAMB3 | c.3512G>A p.C1171Y | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50524019; called by muse, mutect2, varscan2
- LAMC1 | c.1713G>C p.L571F | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV51155502; called by muse, mutect2, varscan2
- LARS2 | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55525796, COSV55529798; called by muse, mutect2, varscan2
- LBX2 | c.458C>T p.S153L (on ENST00000377566 / NM_001282430.2; = p.S149L on NM_001009812.2) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV52036379; called by muse, mutect2, varscan2
- LGR6 | c.949G>T p.D317Y (on ENST00000367278 / NM_001017403.1; = p.D265Y on NM_021636.3) | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV55161723, COSV55168834; called by muse, mutect2, varscan2
- LIFR | c.3185C>T p.S1062F | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54695116; called by muse, mutect2
- LILRA1 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 84/240 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52182854; called by muse, varscan2
- LILRA1 | c.1228C>T p.H410Y | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as rs1440947365, COSV52182869; called by muse, varscan2
- LINGO4 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs143154971; ClinVar: uncertain significance; called by muse, mutect2
- LIPJ | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64245885; called by muse, mutect2, varscan2
- LMO4 | c.236G>C p.R79T | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV65170463; called by muse, mutect2, varscan2
- LRRC1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100906355, COSV63829963; called by muse, mutect2, varscan2
- LRRC66 | c.1687C>A p.H563N | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV58635167, COSV58635348; called by muse, mutect2, varscan2
- LRRCC1 | c.1019G>A p.R340K | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0.01); catalogued as COSV64483328, COSV64484465; called by muse, mutect2, varscan2
- LRRIQ4 | c.252G>T p.R84S | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV61619694; called by muse, mutect2, varscan2
- LTBP3 | c.258G>C p.Q86H | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV57242469; called by muse, mutect2
- LURAP1 | c.66G>C p.K22N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV64338380; called by muse, mutect2, varscan2
- LUZP1 | c.1978G>A p.D660N | Missense Mutation (SNP) | VAF 79/240 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.164); catalogued as COSV56503390; called by muse, mutect2, varscan2
- LZTFL1 | c.486G>C p.E162D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV56111899, COSV99944849; called by muse, mutect2, varscan2
- MAGI3 | c.4074C>G p.I1358M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV56840331; called by mutect2, varscan2
- MAN1B1 | c.301T>A p.Y101N | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as COSV64306819; called by muse, mutect2, varscan2
- MAN1C1 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV56044487; called by muse, mutect2, varscan2
- MAP11 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57587204; called by muse, mutect2, varscan2
- MAP1A | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs766641147, COSV55810927; called by muse, mutect2, varscan2
- MAP2K7 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as COSV60718714; called by muse, mutect2, varscan2
- MAP3K12 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV57234473; called by muse, mutect2, varscan2
- MAP3K14 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.392); catalogued as rs996613711, COSV60924261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MASP1 | c.1368G>C p.Q456H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV56225605; called by muse, mutect2, varscan2
- MATN3 | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV68100282; called by muse, mutect2, varscan2
- MBTD1 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 116/278 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.808); catalogued as COSV64503399; called by muse, mutect2, varscan2
- MC3R | c.552G>C p.E184D | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.069); catalogued as COSV54764431; called by muse, mutect2, varscan2
- MCCC2 | c.803G>A p.R268K | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.03); catalogued as CM034741, CS012212, COSV60155570; called by muse, mutect2, varscan2
- MECR | c.666G>T p.Q222H | Missense Mutation (SNP) | VAF 81/310 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.516); catalogued as COSV55286494, COSV55288404; called by muse, mutect2, varscan2
- MED12 | c.6099G>A p.M2033I | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV61348127; called by muse, varscan2
- MED12L | c.1464C>G p.F488L | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56387773; called by muse, mutect2, varscan2
- MEN1 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as CM1313212, CM970932, COSV53644033, COSV53645917; called by muse, mutect2, varscan2
- METTL25 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV99942287; called by muse, mutect2
- METTL3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53915370; called by muse, mutect2, varscan2
- METTL5 | c.542-2A>G p.X181_splice | Splice Site (SNP) | VAF 34/100 reads (34%) | catalogued as COSV53627222; called by muse, mutect2, varscan2
- MFF | c.856G>C p.D286H | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV58826325; called by muse, mutect2, varscan2
- MFSD14A | c.698C>G p.P233R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1431960973; called by muse, mutect2
- MGAM | c.1543G>C p.E515Q | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV72075124; called by muse, mutect2, varscan2
- MICAL1 | c.1615G>T p.D539Y | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57805704, COSV57806311; called by muse, mutect2, varscan2
- MICALL1 | c.1613C>G p.S538* | Nonsense Mutation (SNP) | VAF 14/84 reads (17%) | catalogued as COSV53243162, COSV99317493; called by muse, varscan2
- MICALL1 | c.1726C>G p.Q576E | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.438); catalogued as COSV53239173, COSV53242107; called by muse, varscan2
- MIPEP | c.244del p.E82Kfs*4 | Frame Shift Del (DEL) | VAF 18/115 reads (16%) | catalogued as COSV101182404, COSV66134787; called by mutect2, pindel, varscan2
- MKI67 | c.832G>C p.D278H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.243); catalogued as COSV64075610; called by muse, mutect2, varscan2
- MLLT1 | c.296G>A p.C99Y | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.46); catalogued as COSV53131622, COSV53131908; called by muse, mutect2, varscan2
- MRPL53 | c.79G>C p.V27L | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV50688827; called by muse, mutect2, varscan2
- MRPS31 | c.258G>C p.E86D | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.435); catalogued as COSV60267726; called by muse, mutect2, varscan2
- MSH6 | c.2067C>G p.F689L | Missense Mutation (SNP) | VAF 56/235 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV52276295; called by muse, mutect2, varscan2
- MTA1 | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58758794; called by muse, mutect2, varscan2
- MTHFD1L | c.1649C>T p.P550L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs767147621, COSV66226361; called by muse, mutect2, varscan2
- MTMR1 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV64898988; called by muse, mutect2, varscan2
- MUC17 | c.9655G>A p.E3219K | Missense Mutation (SNP) | VAF 96/537 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); catalogued as COSV60287856; called by muse, mutect2, varscan2
- MUC6 | c.1720G>C p.E574Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as COSV70145247; called by muse, mutect2, varscan2
- MVP | c.1192-1G>A p.X398_splice | Splice Site (SNP) | VAF 10/41 reads (24%) | catalogued as COSV62422787; called by muse, mutect2, varscan2
- MYCBPAP | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV60409791; called by muse, mutect2, varscan2
- MYO15A | c.3210G>C p.Q1070H | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.264); catalogued as COSV52761058; called by muse, mutect2, varscan2
- MYO1C | c.2186C>T p.A729V (on ENST00000648651 / NM_001080779.2; = p.A694V on NM_033375.5) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV63000048; called by muse, varscan2
- MYO7A | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV68685883; called by muse, mutect2, varscan2
- MYOT | c.598C>G p.Q200E | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV53515550; called by muse, mutect2, varscan2
- MYRF | c.2561C>G p.S854C (on ENST00000278836 / NM_001127392.3; = p.S819C on NM_013279.4) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV53891497; called by muse, mutect2, varscan2
- N4BP2 | c.3985G>A p.E1329K | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV54704581; called by muse, mutect2, varscan2
- NAALAD2 | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV58958361, COSV58963511; called by muse, mutect2, varscan2
- NAPA | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV54551018; called by muse, mutect2, varscan2
- NARS2 | c.589C>G p.L197V | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55253815; called by muse, mutect2, varscan2
- NCKAP1 | c.662C>G p.A221G | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.591); catalogued as COSV62942305; called by muse, mutect2, varscan2
- NCKAP1L | c.2117C>G p.S706C | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV53209794; called by muse, mutect2, varscan2
- NCOA3 | c.2619C>G p.I873M | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.243); catalogued as COSV59070978; called by muse, mutect2, varscan2
- NDUFV1 | c.617G>C p.C206S | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs863224120, COSV59596046; called by muse, mutect2, varscan2
- NEK10 | c.2384C>G p.S795C | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.109); catalogued as COSV55362356; called by muse, mutect2, varscan2
- NFRKB | c.1144C>T p.L382F (on ENST00000446488 / NM_001143835.2; = p.L407F on NM_006165.3) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs201205390, COSV58759278; called by muse, mutect2, varscan2
- NGFR | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.164); catalogued as rs1010649165, COSV50803240; called by muse, mutect2, varscan2
- NIF3L1 | c.829C>G p.H277D (on ENST00000409020 / NM_001369444.1; = p.H250D on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV62900568, COSV62900964; called by muse, mutect2, varscan2
- NLRP11 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.9); catalogued as COSV64088250; called by muse, mutect2, varscan2
- NLRP2 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as rs764556038, COSV54757727; called by muse, mutect2, varscan2
- NLRP2 | c.2686G>A p.E896K | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.103); catalogued as rs990334364, COSV54757736; called by muse, mutect2, varscan2
- NME5 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.046); catalogued as COSV54523234, COSV54523438; called by muse, mutect2, varscan2
- NOL8 | c.3241G>A p.D1081N | Missense Mutation (SNP) | VAF 47/267 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV62636384; called by muse, mutect2, varscan2
- NOMO1 | c.1421G>C p.R474T | Missense Mutation (SNP) | VAF 77/304 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV55060058; called by muse, mutect2, varscan2
- NPRL3 | c.1522G>A p.E508K (on ENST00000611875 / NM_001077350.3; = p.E483K on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as CD162573, COSV54738991; called by mutect2, varscan2
- NR4A2 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV59894762; called by muse, mutect2, varscan2
- NRBP1 | c.305C>G p.S102C | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51995093; called by muse, mutect2, varscan2
- NT5C3A | c.685G>A p.D229N (on ENST00000610140 / NM_001374335.1; = p.D195N on NM_016489.13) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV54239295; called by muse, mutect2, varscan2
- NUP153 | c.3599C>T p.S1200L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV50455520; called by muse, varscan2
- NUP210L | c.1714C>T p.H572Y | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as COSV55152599; called by muse, mutect2, varscan2
- NUP85 | c.60G>C p.K20N | Missense Mutation (SNP) | VAF 35/328 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV55465366; called by muse, varscan2
- NUP88 | c.2200G>A p.D734N | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as COSV52586679, COSV52586914; called by muse, mutect2, varscan2
- OBSCN | c.12631G>T p.D4211Y | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1435821165, COSV52796593, COSV52800439; called by muse, mutect2, varscan2
- ODC1 | c.968A>G p.Y323C | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1322305155, COSV52172969; called by muse, mutect2, varscan2
- ONECUT1 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100009166; called by muse, mutect2, varscan2
- OR10AD1 | c.49C>A p.Q17K | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV59612832; called by muse, mutect2
- OR2A2 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV68872159; called by muse, mutect2, varscan2
- OR5A1 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs574597111, COSV57375852; called by muse, mutect2, varscan2
- OR5D18 | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61737980; called by muse, mutect2, varscan2
- OR5M10 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV73242383; called by muse, mutect2, varscan2
- OR5M10 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as rs776935495, COSV73242357; called by muse, mutect2, varscan2
- OR7C2 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); catalogued as rs199970299, COSV50180279; called by muse, mutect2, varscan2
- OSBPL6 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.034); catalogued as COSV51924003; called by muse, mutect2, varscan2
- OSBPL8 | c.2462G>T p.R821I | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.898); catalogued as COSV53886355; called by muse, mutect2, varscan2
- OTOGL | c.6724G>A p.E2242K (on ENST00000547103; = p.E2233K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54020171; called by muse, mutect2, varscan2
- PACS1 | c.1417C>G p.L473V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs752240688, COSV57698848; called by muse, mutect2, varscan2
- PAFAH1B2 | c.68G>C p.R23P | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59167100; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1136T>C p.M379T (on ENST00000374531 / NM_001037293.2; = p.M411T on NM_053016.6) | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57114097; called by muse, mutect2, varscan2
- PANK1 | c.1442G>A p.G481E | Missense Mutation (SNP) | VAF 79/253 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV56809328; called by muse, mutect2, varscan2
- PAPLN | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs755902550, COSV53718275, COSV53721003; called by muse, mutect2, varscan2
- PARP10 | c.1052C>G p.S351W | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.682); catalogued as COSV57299078; called by muse, mutect2, varscan2
- PATZ1 | c.1961C>A p.S654Y | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV56744471, COSV56744774; called by muse, mutect2, varscan2
- PBX2 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.138); catalogued as COSV66709159; called by muse, mutect2, varscan2
- PCDH18 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV61270303; called by muse, mutect2, varscan2
- PCDHB13 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV53398990; called by muse, mutect2, varscan2
- PCDHGB4 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99537624; called by muse, mutect2, varscan2
- PCIF1 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs531224212, COSV65026773; called by muse, mutect2, varscan2
- PCNX4 | c.2806G>C p.D936H (on ENST00000406854 / NM_001330177.2; = p.D702H on NM_022495.5) | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs752433727, COSV58305971; called by muse, mutect2, varscan2
- PDE4DIP | c.3407C>T p.P1136L | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57711997; called by muse, mutect2, varscan2
- PDZRN3 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV55208379; called by muse, mutect2, varscan2
- PGA5 | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56716364; called by muse, mutect2, varscan2
- PGBD1 | c.654G>C p.K218N | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as COSV52551752, COSV52554823; called by muse, mutect2, varscan2
- PHF24 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.57); catalogued as rs750087334, COSV54275660; called by muse, mutect2, varscan2
- PHKA2 | c.3332G>A p.R1111Q | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs374245493, COSV66052336; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHLPP2 | c.20G>T p.R7I | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV62425933; called by muse, mutect2, varscan2
- PIANP | c.726C>A p.F242L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV57708249, COSV57708254; called by muse, mutect2, varscan2
- PIGS | c.300C>G p.I100M | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV52023284, COSV52025960; called by muse, mutect2, varscan2
- PIK3C2A | c.3100C>G p.L1034V | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.492); catalogued as rs1565252733, COSV56404917; called by muse, mutect2, varscan2
- PIP5K1A | c.1545G>C p.Q515H (on ENST00000368888 / NM_001135638.2; = p.Q502H on NM_003557.3) | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.615); catalogued as COSV62957410, COSV62959259; called by muse, mutect2, varscan2
- PIPOX | c.961T>C p.Y321H | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60142766; called by muse, mutect2, varscan2
- PKHD1L1 | c.4841C>T p.S1614L | Missense Mutation (SNP) | VAF 39/291 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV65747799; called by muse, mutect2, varscan2
- PKHD1L1 | c.9196G>A p.D3066N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.9); catalogued as COSV65747803; called by muse, mutect2, varscan2
- PLEKHA8 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1275588712, COSV51652999; called by muse, mutect2, varscan2
- PLEKHB2 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52176965; called by muse, mutect2, varscan2
- PLK3 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.873); catalogued as COSV59500473; called by muse, mutect2, varscan2
- PLTP | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV62465471; called by muse, mutect2, varscan2
- PLXNA4 | c.5342C>T p.S1781F | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58144502; called by muse, mutect2, varscan2
- PMPCB | c.661A>G p.I221V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as rs149104855; called by muse, mutect2, varscan2
- PNPT1 | c.769C>A p.Q257K | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV53178787; called by muse, mutect2, varscan2
- POC1A | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as rs757612033, COSV56592524; called by muse, mutect2, varscan2
- POLR3A | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV64931544; called by muse, mutect2
- POLRMT | c.290G>C p.G97A | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV73933366; called by muse, mutect2, varscan2
- POM121 | c.3527G>C p.G1176A (on ENST00000434423; = p.G911A on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1159191999; called by muse, mutect2, varscan2
- POMT1 | c.269G>C p.R90T | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.639); catalogued as COSV61226834; called by muse, varscan2
- PPCS | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as rs1364205580, COSV65333748; called by muse, mutect2, varscan2
- PPOX | c.1292-1G>C p.X431_splice | Splice Site (SNP) | VAF 40/418 reads (10%) | catalogued as COSV60527632; called by muse, mutect2
- PPP1R10 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV64739885; called by muse, mutect2, varscan2
- PPP1R13B | c.3254G>A p.R1085Q | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs548424756, COSV52453989; called by muse, mutect2, varscan2
- PPP1R36 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as COSV53903120; called by muse, mutect2, varscan2
- PPP3CB | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV61153627; called by muse, mutect2, varscan2
- PPP3R2 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV62456239; called by muse, mutect2, varscan2
- PRAMEF12 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 51/179 reads (28%) | catalogued as COSV63215607, COSV99080813; called by muse, mutect2, varscan2
- PRDM7 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.112); catalogued as COSV68322465, COSV68322654; called by muse, mutect2, varscan2
- PRDX6 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as rs1006730878, COSV61165472; called by muse, mutect2, varscan2
- PRKCQ | c.393G>T p.M131I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV54115147; called by muse, mutect2, varscan2
- PRKD3 | c.627G>C p.K209N | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.317); catalogued as COSV52215613; called by muse, mutect2, varscan2
- PRMT9 | c.1648C>G p.P550A | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV59360526; called by muse, mutect2, varscan2
- PRR15L | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 62/146 reads (42%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.986); catalogued as COSV56023732, COSV56024341; called by muse, mutect2, varscan2
- PRRC2A | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as COSV63224868; called by muse, mutect2, varscan2
- PSMC6 | c.418G>A p.D140N (on ENST00000612399; = p.D126N on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV71629078; called by muse, mutect2, varscan2
- PTCHD4 | c.2430C>A p.F810L | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.695); catalogued as COSV100259647, COSV100262138, COSV59791038; called by muse, mutect2, varscan2
- PTPN4 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.649); catalogued as COSV55305322; called by muse, mutect2, varscan2
- PTPRZ1 | c.34C>G p.Q12E | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV66441610; called by muse, mutect2, varscan2
- PXDNL | c.2191G>A p.D731N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62483481, COSV99080565; called by muse, varscan2
- PXMP2 | c.413C>A p.S138* | Nonsense Mutation (SNP) | VAF 20/152 reads (13%) | catalogued as COSV58095683; called by muse, mutect2, varscan2
- PZP | c.3937G>C p.E1313Q | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as COSV54365284; called by muse, mutect2, varscan2
- PZP | c.2057C>G p.S686* | Nonsense Mutation (SNP) | VAF 14/110 reads (13%) | catalogued as COSV54361212; called by muse, mutect2
- QRICH1 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.262); catalogued as COSV62616684; called by muse, mutect2, varscan2
- RAB37 | c.302G>A p.R101K (on ENST00000392613 / NM_001006638.3; = p.R94K on NM_175738.5) | Missense Mutation (SNP) | VAF 71/191 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs527644258, COSV61196410; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2042C>T p.S681L | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99921262; called by muse, mutect2
- RAN | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200416921, COSV54563246; called by muse, mutect2, varscan2
- RASA3 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs754584819; called by muse, mutect2
- RB1 | c.1190C>G p.S397* | Nonsense Mutation (SNP) | VAF 23/209 reads (11%) | catalogued as CM961227, COSV57295856, COSV57306166, COSV57308688; called by muse, mutect2, varscan2
- RBAK | c.2128G>C p.D710H | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV62332029; called by muse, mutect2, varscan2
- RBBP6 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV60506990; called by muse, mutect2, varscan2
- RBM25 | c.2408C>T p.S803L | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as COSV56201325; called by muse, mutect2, varscan2
- RBM47 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs745735810, COSV55937358, COSV99920781; called by muse, mutect2, varscan2
- RDX | c.234C>G p.F78L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.568); catalogued as rs948868930, COSV100562980, COSV58195404; called by muse, mutect2, varscan2
- RECQL4 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as rs1035926081, COSV99468381; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RENBP | c.960G>A p.M320I | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV64170297; called by muse, mutect2, varscan2
- RENBP | c.739C>A p.P247T | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as COSV64170306; called by muse, mutect2, varscan2
- REPS2 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV58185351; called by muse, mutect2, varscan2
- RERE | c.528G>C p.K176N | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV61938720; called by muse, mutect2, varscan2
- RGS16 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV62375846; called by muse, mutect2, varscan2
- RHBDF1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV51956857; called by muse, mutect2, varscan2
- RHBDL2 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV56708949; called by muse, mutect2, varscan2
- RHCE | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53801984; called by muse, mutect2, varscan2
- RHOB | c.486G>C p.K162N | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as COSV55356822; called by muse, mutect2, varscan2
- RNASEH1 | c.524G>T p.R175I | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59439237; called by muse, mutect2, varscan2
- RNF4 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58642179; called by muse, mutect2
- RORC | c.60G>C p.K20N | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV59094371; called by muse, mutect2
- RPIA | c.366G>C p.E122D | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.1); catalogued as COSV52170737, COSV52171774; called by muse, mutect2, varscan2
- RRP12 | c.3481G>A p.D1161N | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV59669679; called by muse, mutect2, varscan2
- RSAD2 | c.320G>A p.R107K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.058); catalogued as rs751892211, COSV65908626; called by muse, mutect2, varscan2
- RTL10 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 21/116 reads (18%) | catalogued as rs750569833; called by muse, mutect2, varscan2
- RTL4 | c.437C>G p.P146R | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.051); catalogued as COSV100465722, COSV61206926, COSV61207477; called by muse, mutect2, varscan2
- RTN3 | c.2866G>C p.D956H (on ENST00000377819 / NM_001265589.2; = p.D160H on NM_006054.4) | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58030346; called by muse, mutect2, varscan2
- SASH1 | c.1348C>G p.L450V | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66563629; called by muse, mutect2, varscan2
- SBDS | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.162); catalogued as COSV55888142, COSV55888808; called by muse, mutect2
- SCAP | c.2560C>G p.L854V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV55546266; called by mutect2, varscan2
- SCAPER | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV57746841; called by muse, mutect2, varscan2
- SCEL | c.61C>G p.Q21E | Missense Mutation (SNP) | VAF 42/311 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV62994072; called by muse, mutect2, varscan2
- SDHC | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 125/205 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553262444, COSV61368898; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SENP1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs553082909, COSV50286820; called by muse, mutect2, varscan2
- SENP6 | c.2617G>C p.E873Q | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.676); catalogued as COSV64187472; called by muse, mutect2, varscan2
- SEPTIN11 | c.507G>C p.M169I | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV53583429; called by muse, mutect2, varscan2
- SEPTIN11 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV53583446; called by muse, mutect2, varscan2
- SERPINB13 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs751796215, COSV54029825; called by muse, mutect2, varscan2
- SETDB1 | c.3826G>C p.E1276Q (on ENST00000271640 / NM_001366417.1; = p.E1275Q on NM_012432.4) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.205); catalogued as COSV54988186, COSV54988929; called by muse, mutect2, varscan2
- SF3B1 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV59220854; called by muse, mutect2, varscan2
- SFXN5 | c.489C>A p.F163L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as COSV55588584; called by muse, mutect2, varscan2
- SHANK1 | c.5383G>C p.D1795H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV53256551; called by muse, mutect2
- SIRT1 | c.1411C>T p.H471Y | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as COSV53019294; called by muse, mutect2, varscan2
- SKA2 | c.307C>A p.L103M | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV57522570; called by muse, mutect2, varscan2
- SLC17A1 | c.965C>G p.S322* | Nonsense Mutation (SNP) | VAF 23/90 reads (26%) | catalogued as COSV55078834, COSV55082287; called by muse, mutect2, varscan2
- SLC25A19 | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57468095; called by muse, varscan2
- SLC28A3 | c.1118G>A p.G373E | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66154140; called by muse, mutect2, varscan2
- SLC35A5 | c.1063C>G p.P355A | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV53727484, COSV99656789; called by muse, mutect2, varscan2
- SLC35G2 | c.1116C>G p.I372M | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.15); catalogued as rs564732566, COSV67588690; called by muse, mutect2, varscan2
- SLC4A5 | c.2188G>A p.G730R | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755433686, COSV61030440; called by muse, varscan2
- SLC9C2 | c.2808G>T p.M936I | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV62947320; called by muse, mutect2, varscan2
- SMC1B | c.1570C>T p.H524Y | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV62531913, COSV62533388; called by muse, mutect2, varscan2
- SMG9 | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54215584; called by muse, mutect2, varscan2
- SND1 | c.1455-1G>A p.X485_splice | Splice Site (SNP) | VAF 9/52 reads (17%) | catalogued as rs1299578565, COSV61245036; called by muse, mutect2, varscan2
- SNX10 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.998); catalogued as rs1350447913, COSV58401742; called by muse, mutect2, varscan2
- SORL1 | c.2327C>T p.S776L | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs766557470, COSV52758318; called by muse, mutect2, varscan2
- SP1 | c.1054C>T p.Q352* (on ENST00000327443 / NM_138473.3; = p.Q345* on NM_003109.1) | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100540894; called by muse, mutect2, varscan2
- SP1 | c.1337C>G p.S446C (on ENST00000327443 / NM_138473.3; = p.S439C on NM_003109.1) | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs1447055936, COSV59404262; called by muse, mutect2, varscan2
- SPAG8 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV52414793; called by muse, mutect2, varscan2
- SPATA13 | c.1299G>C p.K433N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV57979570; called by muse, mutect2, varscan2
- SPDYA | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs771698422, COSV61856457; called by muse, mutect2, varscan2
- SPECC1 | c.2062G>C p.E688Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV54962254; called by muse, mutect2, varscan2
- SPG11 | c.3304G>T p.E1102* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as rs1459084420; called by muse, mutect2, varscan2
- SPINDOC | c.1100C>A p.S367Y | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV53693240, COSV99588414; called by muse, mutect2, varscan2
- SPTA1 | c.5127G>C p.L1709F | Missense Mutation (SNP) | VAF 17/217 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63753393, COSV63756762; called by muse, mutect2
- SPTBN2 | c.3922G>A p.E1308K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs1165162584, COSV59456828; called by muse, mutect2, varscan2
- SPTBN5 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); catalogued as rs371870337, COSV58022700; called by muse, mutect2, varscan2
- SSRP1 | c.867G>A p.M289I | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs1336619542, COSV53479024; called by muse, mutect2, varscan2
- STK17B | c.743C>G p.S248C | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV55829384; called by muse, mutect2, varscan2
- STXBP4 | c.1538A>G p.Y513C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64466211; called by muse, mutect2, varscan2
- SULT6B1 | c.577C>G p.L193V (on ENST00000535679 / NM_001367551.1; = p.L155V on NM_001032377.2) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV53195377; called by muse, mutect2, varscan2
- SULT6B1 | c.313-1G>C p.X105_splice (on ENST00000535679 / NM_001367551.1; = p.X67_splice on NM_001032377.2) | Splice Site (SNP) | VAF 20/68 reads (29%) | catalogued as COSV53195393; called by muse, mutect2, varscan2
- SYNE1 | c.16001C>T p.S5334F (on ENST00000367255 / NM_182961.4; = p.S5263F on NM_033071.3) | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV54967085; called by muse, mutect2, varscan2
- SYNM | c.4213C>T p.R1405* | Nonsense Mutation (SNP) | VAF 50/231 reads (22%) | catalogued as rs782243596; called by muse, mutect2, varscan2
- SZT2 | c.8190G>C p.E2730D (on ENST00000634258 / NM_001365999.1; = p.E2673D on NM_015284.4) | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV65171908; called by muse, mutect2, varscan2
- TAB3 | c.632G>C p.R211T | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.84); PolyPhen benign (0.175); catalogued as COSV55835678; called by muse, mutect2, varscan2
- TACR3 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1008776547, CM103249, COSV59199133; called by muse, mutect2, varscan2
- TAF4 | c.2692G>T p.V898L | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV53340498; called by muse, mutect2, varscan2
- TANC1 | c.2581G>C p.E861Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV55092455; called by muse, varscan2
- TARS2 | c.393C>G p.F131L | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV64696308; called by muse, mutect2, varscan2
- TATDN3 | c.61G>C p.D21H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV65325511; called by muse, mutect2, varscan2
- TBC1D31 | c.2561G>A p.R854K | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV54868611; called by muse, mutect2, varscan2
- TBC1D8 | c.2944G>A p.E982K | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.908); catalogued as COSV51822509; called by muse, mutect2, varscan2
- TBC1D9 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV71308076; called by muse, varscan2
- TBCK | c.1009G>A p.E337K (on ENST00000273980 / NM_001163436.4; = p.E274K on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.805); catalogued as COSV56759109, COSV99912973; called by muse, mutect2, varscan2
- TCEA2 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58658562; called by muse, mutect2, varscan2
- TCEAL1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.996); catalogued as COSV65461196; called by muse, mutect2, varscan2
- TDRD9 | c.1395G>C p.L465F | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59151338; called by muse, mutect2, varscan2
- TEKT2 | c.93G>C p.Q31H | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52881516; called by muse, mutect2, varscan2
- TELO2 | c.49C>G p.H17D | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV51979770; called by muse, mutect2, varscan2
- TENM4 | c.3576G>C p.E1192D | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV53648714, COSV53668649, COSV53671592; called by muse, mutect2, varscan2
- TFG | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 38/122 reads (31%) | catalogued as COSV53749908; called by muse, mutect2, varscan2
- THOP1 | c.251T>C p.F84S | Missense Mutation (SNP) | VAF 81/237 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV57019787; called by muse, mutect2, varscan2
- THRAP3 | c.2435C>G p.S812* | Nonsense Mutation (SNP) | VAF 5/57 reads (9%) | catalogued as COSV100663410; called by muse, mutect2
- TICRR | c.1110C>G p.S370R | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.117); catalogued as COSV51544210; called by muse, mutect2, varscan2
- TJP2 | c.3256G>A p.E1086K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774499739, COSV55270308; called by muse, mutect2, varscan2
- TLCD1 | c.711G>T p.K237N | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV52046920; called by muse, mutect2, varscan2
- TLCD1 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.096); catalogued as rs200266791, COSV52046928; called by muse, mutect2, varscan2
- TLR3 | c.2184G>C p.W728C | Missense Mutation (SNP) | VAF 80/220 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57169589; called by muse, mutect2, varscan2
- TMEM106C | c.95A>T p.E32V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.502); catalogued as COSV56743164; called by muse, mutect2, varscan2
- TMEM132E | c.2573G>T p.G858V (on ENST00000321639; = p.G948V on NM_001304438.2) | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV58698790, COSV58698987; called by muse, mutect2, varscan2
- TMEM245 | c.2396C>T p.S799L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV65823640; called by muse, mutect2, varscan2
- TNC | c.3539C>T p.A1180V | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV60787568; called by muse, mutect2, varscan2
- TNFRSF21 | c.1460G>C p.R487T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57283736, COSV57285251; called by muse, mutect2, varscan2
- TNFRSF4 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs754604681, COSV64878865; ClinVar: uncertain significance; called by mutect2, varscan2
- TNXB | c.6706C>T p.R2236C (on ENST00000647633; = p.R1989C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs371681556; called by muse, mutect2, varscan2
- TPO | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.155); catalogued as COSV61106346; called by muse, mutect2, varscan2
- TPP2 | c.1370G>A p.G457E | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65753784; called by muse, mutect2, varscan2
- TPRKB | c.279G>C p.L93F | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.12); catalogued as COSV55541569; called by muse, mutect2, varscan2
- TRADD | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs771540228, COSV50758084; called by muse, varscan2
- TRAPPC11 | c.1419G>A p.L473= | Splice Region (SNP) | VAF 23/71 reads (32%) | catalogued as COSV100591952, COSV58217806; called by muse, mutect2, varscan2
- TRAPPC4 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as COSV57723282; called by muse, mutect2, varscan2
- TRARG1 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.608); catalogued as COSV61562502, COSV61563020; called by muse, mutect2, varscan2
- TRIM46 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55279678; called by muse, mutect2, varscan2
- TRIP12 | c.441G>T p.Q147H | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV52268553; called by muse, mutect2, varscan2
- TRIT1 | c.227G>C p.R76T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as COSV57549210; called by muse, mutect2, varscan2
- TRPC5 | c.2804C>T p.S935L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.1); catalogued as COSV53297402; called by muse, mutect2, varscan2
- TTI1 | c.2384G>C p.R795T | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs577513143, COSV65060327, COSV65061252, COSV65062519; called by muse, mutect2, varscan2
- TTN | c.13189G>A p.G4397S (on ENST00000591111; = p.G4351S on NM_003319.4) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | PolyPhen possibly damaging (0.878); catalogued as rs757944467, COSV60199680, COSV60301256; called by muse, mutect2, varscan2
- TTN | c.11476C>A p.L3826I (on ENST00000591111; = p.L3780I on NM_003319.4) | Missense Mutation (SNP) | VAF 31/158 reads (20%) | catalogued as COSV60199694; called by muse, mutect2, varscan2
- TUT4 | c.2662G>T p.D888Y | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV57116977; called by muse, mutect2, varscan2
- TUT4 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as COSV57116988; called by muse, mutect2, varscan2
- TXK | c.487C>G p.L163V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as COSV51917739; called by muse, mutect2, varscan2
- TXLNA | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV65313792, COSV65314847; called by muse, mutect2, varscan2
- UBE2J1 | c.129C>A p.F43L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70561900; called by muse, mutect2, varscan2
- UBFD1 | c.894C>G p.I298M | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54842625; called by muse, mutect2, varscan2
- UBL7 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.254); catalogued as COSV63706480; called by muse, mutect2, varscan2
- UBP1 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV52146637; called by muse, mutect2, varscan2
- UGT2B28 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV59432192; called by muse, mutect2, varscan2
- UNC45B | c.1932C>G p.I644M | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.031); catalogued as rs781749893; called by muse, mutect2
- USF3 | c.1290G>C p.Q430H | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV57075262; called by muse, mutect2, varscan2
- USP9X | c.1657G>C p.D553H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61072357, COSV61074646; called by muse, mutect2, varscan2
- UTP20 | c.2124G>C p.Q708H | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1414015424, COSV55381545, COSV99881336; called by muse, mutect2, varscan2
- UTS2R | c.254C>A p.S85Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57453480; called by muse, mutect2, varscan2
- VIT | c.1597C>T p.R533C (on ENST00000389975 / NM_001177969.1; = p.R548C on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781780147, COSV64895682, COSV64896627; called by muse, mutect2, varscan2
- VPS13D | c.11611G>A p.E3871K | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.439); catalogued as COSV50657194; called by muse, mutect2, varscan2
- VPS4A | c.720G>C p.E240D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV54751301; called by muse, mutect2, varscan2
- VWA3B | c.2067T>G p.S689R | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV68244742; called by muse, mutect2, varscan2
- WDR17 | c.3735G>C p.K1245N | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as rs754271078, COSV54578738; called by muse, mutect2, varscan2
- WDR24 | c.1893C>G p.D631E (on ENST00000248142; = p.D501E on NM_032259.4) | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV50199996; called by muse, mutect2, varscan2
- WDR44 | c.2291C>G p.S764C | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54166124; called by muse, mutect2, varscan2
- WDR45 | c.626C>G p.S209* (on ENST00000376372 / NM_001029896.2; = p.S210* on NM_007075.3) | Nonsense Mutation (SNP) | VAF 23/50 reads (46%) | catalogued as COSV59876216; called by muse, mutect2, varscan2
- WNT7B | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.086); catalogued as rs1164975115, COSV59748762, COSV59751895; called by muse, mutect2, varscan2
- YARS1 | c.1293G>T p.M431I | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as COSV65114619; called by muse, mutect2, varscan2
- ZBTB20 | c.1090G>A p.E364K (on ENST00000474710 / NM_001164342.2; = p.E291K on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs1254924801, COSV61858733; called by muse, mutect2, varscan2
- ZC3H3 | c.769C>G p.P257A | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs566613895, COSV52792418; called by muse, mutect2, varscan2
- ZDBF2 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV65628132; called by muse, mutect2, varscan2
- ZER1 | c.2086C>G p.P696A | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs773864411, COSV52567378; called by mutect2, varscan2
- ZFHX4 | c.3027C>G p.N1009K | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51474567; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2357G>A p.R786K | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.087); catalogued as rs1314627262, COSV60157818; called by muse, mutect2, varscan2
- ZMAT4 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 79/264 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1344682333, COSV52703484; called by muse, mutect2, varscan2
- ZMYM1 | c.2199C>G p.F733L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1314761115, COSV63252640; called by muse, mutect2, varscan2
- ZNF132 | c.177G>C p.Q59H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54235524; called by muse, mutect2, varscan2
- ZNF157 | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV65659299; called by muse, mutect2, varscan2
- ZNF214 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV53482895; called by muse, mutect2, varscan2
- ZNF225 | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.801); catalogued as COSV53472419; called by muse, mutect2, varscan2
- ZNF329 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63772636; called by muse, mutect2, varscan2
- ZNF335 | c.3628G>A p.D1210N | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59818008, COSV59818905; called by muse, varscan2
- ZNF440 | c.1318C>T p.Q440* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as COSV58370491, COSV58372642; called by muse, mutect2, varscan2
- ZNF484 | c.132G>C p.L44F | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV60258796; called by muse, mutect2, varscan2
- ZNF557 | c.793G>T p.E265* (on ENST00000414706 / NM_001044388.2; = p.E272* on NM_024341.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 21/106 reads (20%) | catalogued as COSV53274039, COSV53274213; called by muse, mutect2, varscan2
- ZNF578 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 65/235 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1167250897, COSV69737096; called by muse, mutect2, varscan2
- ZNF624 | c.83G>C p.R28P | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60939727, COSV60940808; called by muse, mutect2
- ZNF781 | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV62202160; called by muse, mutect2, varscan2
- ZNF813 | c.1849A>G p.N617D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV67177367; called by muse, mutect2, varscan2
- ZNFX1 | c.347G>C p.R116T | Missense Mutation (SNP) | VAF 64/325 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.796); catalogued as rs751233949, COSV65575509, COSV65576985; called by muse, mutect2, varscan2
- ZPBP | c.641C>G p.S214C | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV50429201; called by muse, mutect2, varscan2
- ACACA | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- ADAMTS13 | c.4255C>T p.Q1419* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2
- ARFGAP3 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 75/193 reads (39%) | called by muse, mutect2, varscan2
- ATF6B | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BIRC6 | c.949C>G p.Q317E | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.438); called by muse, mutect2
- CACNB1 | c.203C>G p.S68* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | called by muse, mutect2, varscan2
- CASKIN1 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- CCDC14 | c.2275C>T p.Q759* (on ENST00000488653; = p.Q711* on NM_022757.5) | Nonsense Mutation (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- CCL16 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2
- CFHR4 | c.1279G>T p.E427* (on ENST00000367416 / NM_001201551.2; = p.E181* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 17/82 reads (21%) | called by muse, mutect2, varscan2
- CHERP | c.6G>C p.E2D | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- CNR2 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2, varscan2
- COL5A1 | c.3796G>A p.D1266N | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DDAH1 | c.857G>C p.*286Sext*43 | Nonstop Mutation (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- DECR1 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 20/218 reads (9%) | called by muse, mutect2
- DEUP1 | c.311C>G p.T104R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.929); called by muse, mutect2
- DHX33 | c.1820C>G p.S607* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- DNAH3 | c.2293G>T p.E765* | Nonsense Mutation (SNP) | VAF 49/171 reads (29%) | called by muse, mutect2, varscan2
- DQX1 | c.1397C>G p.S466* | Nonsense Mutation (SNP) | VAF 35/247 reads (14%) | called by muse, mutect2, varscan2
- DUSP7 | c.165G>T p.K55N | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- FAM83H | c.1463A>G p.D488G | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, varscan2
- FBXW5 | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- FOXL2 | c.1130G>C p.*377Sext*31 | Nonstop Mutation (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- GDF10 | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2
- GGNBP2 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GGT1 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- ISM1 | c.883_900del p.D295_W300del | In Frame Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- KCNJ2 | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- KRTAP5-7 | c.326C>G p.S109* | Nonsense Mutation (SNP) | VAF 83/303 reads (27%) | called by muse, varscan2
- LDLRAD3 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- LGR6 | c.1603G>T p.E535* (on ENST00000367278 / NM_001017403.1; = p.E483* on NM_021636.3) | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- LRFN4 | c.1419C>A p.C473* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | called by muse, varscan2
- LZTS1 | c.1048G>T p.E350* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- MBNL2 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- MUC17 | c.10186G>T p.E3396* | Nonsense Mutation (SNP) | VAF 102/551 reads (19%) | called by muse, mutect2, varscan2
- MUC3A | c.7208C>T p.S2403L | Missense Mutation (SNP) | VAF 116/279 reads (42%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MUC4 | c.2396C>A p.S799* | Nonsense Mutation (SNP) | VAF 16/152 reads (11%) | called by muse, mutect2
- NOP2 | c.343G>T p.E115* (on ENST00000322166 / NM_001258308.2; = p.E111* on NM_006170.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- NTHL1 | c.829G>T p.E277* (on ENST00000219066; = p.E269* on NM_002528.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 30/107 reads (28%) | called by muse, mutect2, varscan2
- OVCH1 | c.2708C>G p.S903* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- PAPOLA | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- PLD3 | c.25G>T p.E9* | Nonsense Mutation (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
- PPL | c.5123C>G p.S1708* | Nonsense Mutation (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- RRP1B | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- SBK1 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- SCN1A | c.743C>G p.S248* | Nonsense Mutation (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- SERPINE1 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- SF3A1 | c.2086G>T p.E696* | Nonsense Mutation (SNP) | VAF 27/104 reads (26%) | called by muse, mutect2, varscan2
- SLC13A3 | c.1577C>A p.S526* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- SLC22A14 | c.1769C>G p.S590* | Nonsense Mutation (SNP) | VAF 25/143 reads (17%) | called by muse, mutect2, varscan2
- SLC35B2 | c.886_890del p.K296Vfs*39 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | called by mutect2, pindel, varscan2
- SLC4A1AP | c.1972G>T p.E658* | Nonsense Mutation (SNP) | VAF 31/119 reads (26%) | called by muse, mutect2, varscan2
- SOD1 | c.323C>G p.S108* | Nonsense Mutation (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2, varscan2
- SORL1 | c.1124C>G p.S375* | Nonsense Mutation (SNP) | VAF 15/88 reads (17%) | called by muse, mutect2, varscan2
- SPARCL1 | c.1994G>C p.*665Sext*16 | Nonstop Mutation (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- SPHK2 | c.1241C>A p.S414* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- ST18 | c.1972C>T p.Q658* | Nonsense Mutation (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- SUPT5H | c.2288C>A p.S763* | Nonsense Mutation (SNP) | VAF 17/111 reads (15%) | called by muse, mutect2, varscan2
- TADA2A | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- TAF13 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 44/309 reads (14%) | called by muse, mutect2, varscan2
- TAX1BP1 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.034); called by muse, mutect2
- TBCA | c.186G>T p.M62I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- TCHH | c.2401G>T p.E801* | Nonsense Mutation (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2, varscan2
- TIMD4 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- TMEM63C | c.1451C>G p.S484* | Nonsense Mutation (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- TNRC18 | c.8255G>C p.R2752T | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TRBV3-1 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- XPC | c.2411C>T p.S804F | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2
- ZHX3 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- ZNF577 | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2
- ZNF629 | c.173C>G p.S58* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- ZXDB | c.1577C>A p.S526Y | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ABCG5 | c.1740C>T p.F580= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV53184368, COSV99571165; called by muse, mutect2, varscan2
- ACACB | c.9G>A p.L3= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV58140401; called by muse, mutect2, varscan2
- ACE2 | c.1507C>T p.L503= | Silent (SNP) | VAF 57/210 reads (27%) | catalogued as COSV53026298; called by muse, mutect2, varscan2
- ACO1 | c.951C>T p.I317= | Silent (SNP) | VAF 29/129 reads (22%) | catalogued as rs750587886, COSV59382306; called by muse, mutect2, varscan2
- ADAR | c.1389G>A p.L463= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV52718227; called by muse, mutect2, varscan2
- ADGRG5 | c.1260C>T p.G420= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs763751363, COSV61082589; called by muse, mutect2, varscan2
- ADRA2C | c.657C>T p.F219= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV57467820; called by muse, mutect2, varscan2
- AFF1 | c.2289G>A p.V763= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV57122049; called by muse, mutect2, varscan2
- AGR2 | c.45C>G p.L15= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV68597116; called by muse, mutect2, varscan2
- AK7 | c.1593G>A p.L531= | Silent (SNP) | VAF 23/205 reads (11%) | catalogued as COSV50876483; called by muse, mutect2, varscan2
- ANKRD11 | c.6603A>G p.A2201= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV56366161; called by muse, mutect2, varscan2
- APLP1 | c.1152C>T p.I384= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as COSV55705308; called by muse, mutect2, varscan2
- APOBEC3D | c.612G>A p.P204= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as rs779214802, COSV53327491; called by muse, mutect2, varscan2
- APOBEC3G | c.321C>T p.F107= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as COSV68470551; called by muse, mutect2, varscan2
- ARHGAP25 | c.1908C>G p.V636= (on ENST00000409202 / NM_001007231.3; = p.V628= on NM_014882.3) | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV54905397; called by muse, mutect2, varscan2
- ARHGEF35 | c.1368C>T p.I456= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs200115857, COSV65312838; called by muse, mutect2, varscan2
- ARSG | c.621C>A p.L207= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV101477873, COSV71593698; called by muse, mutect2, varscan2
- ASF1B | c.339C>G p.V113= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV54616562; called by muse, varscan2
- ASF1B | c.288C>T p.L96= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs751415634, COSV54616575; called by muse, varscan2
- ATG2B | c.882G>A p.L294= | Silent (SNP) | VAF 89/181 reads (49%) | catalogued as COSV63423102; called by muse, mutect2, varscan2
- ATP2B1 | c.3009C>T p.I1003= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV53804100, COSV53810279; called by muse, mutect2, varscan2
- ATP5MC1 | c.321C>G p.L107= | Silent (SNP) | VAF 123/266 reads (46%) | catalogued as COSV63506170, COSV63506189; called by muse, mutect2, varscan2
- ATP7A | c.519G>A p.L173= | Silent (SNP) | VAF 53/313 reads (17%) | catalogued as COSV58450225; called by muse, mutect2, varscan2
- BLOC1S2 | c.111C>T p.I37= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs759803168, COSV58397463; called by muse, mutect2, varscan2
- BRCA2 | c.6615G>T p.V2205= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as COSV66458273; called by muse, mutect2, varscan2
- C10orf82 | c.207C>G p.V69= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV65024739; called by muse, mutect2, varscan2
- C12orf4 | c.297G>A p.A99= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as rs751707878, COSV54208314; called by muse, mutect2, varscan2
- C2CD5 | c.15G>A p.L5= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV61726092; called by muse, mutect2, varscan2
- CACNA1S | c.3138C>T p.I1046= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV62941764; called by muse, mutect2, varscan2
- CACNA1S | c.2688G>A p.L896= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs945772592, COSV62941771; called by muse, mutect2, varscan2
- CAPN5 | c.717G>C p.L239= (on ENST00000456580; = p.L199= on NM_004055.5) | Silent (SNP) | VAF 48/380 reads (13%) | catalogued as COSV53689801; called by muse, mutect2, varscan2
- CCDC136 | c.2673G>A p.L891= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV52802352; called by muse, mutect2, varscan2
- CCDC40 | c.2286G>A p.L762= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as COSV66476128; called by muse, mutect2, varscan2
- CD37 | c.501G>A p.L167= | Silent (SNP) | VAF 20/135 reads (15%) | catalogued as rs775162414, COSV60544918; called by muse, mutect2, varscan2
- CD3G | c.369C>T p.I123= | Silent (SNP) | VAF 27/136 reads (20%) | catalogued as rs769843997, COSV52675530, COSV99416684; called by muse, mutect2, varscan2
- CDC25C | c.1137C>T p.F379= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV60400442; called by muse, mutect2, varscan2
- CDC45 | c.1692C>A p.L564= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV54246975; called by muse, mutect2, varscan2
- CDH10 | c.591A>G p.R197= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as COSV52588887; called by muse, mutect2
- CEACAM1 | c.693G>A p.L231= | Silent (SNP) | VAF 28/224 reads (13%) | catalogued as COSV50729625; called by muse, mutect2, varscan2
- CEL | c.486C>T p.V162= (on ENST00000673714; = p.V159= on NM_001807.6) | Silent (SNP) | VAF 49/265 reads (18%) | catalogued as COSV60828617; called by muse, mutect2, varscan2
- CELA3A | c.432C>A p.L144= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV51585365; called by muse, mutect2, varscan2
- CELF5 | c.1050G>C p.P350= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV53013340; called by muse, mutect2, varscan2
- CENPF | c.8217C>A p.L2739= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV65276922; called by muse, mutect2, varscan2
- CFAP61 | c.1725G>T p.L575= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV55638522; called by muse, mutect2, varscan2
- CFHR1 | c.531G>A p.R177= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV57628132; called by muse, mutect2, varscan2
- CIART | c.813C>T p.L271= | Silent (SNP) | VAF 17/214 reads (8%) | catalogued as COSV51745241; called by muse, mutect2
- CLCN6 | c.2559C>T p.L853= | Silent (SNP) | VAF 42/139 reads (30%) | catalogued as rs184749729, COSV56741706, COSV56741794; called by muse, mutect2, varscan2
- CLEC4G | c.675G>C p.L225= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV61003773; called by muse, mutect2, varscan2
- CMKLR1 | c.813C>T p.L271= (on ENST00000312143 / NM_001142344.2; = p.L269= on NM_004072.3) | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV56440444; called by muse, mutect2, varscan2
- CNKSR1 | c.138C>T p.L46= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as rs772465917, COSV64163745; called by muse, mutect2, varscan2
- CNTN3 | c.1743G>A p.T581= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs749695157, COSV55178489, COSV55183551; called by muse, mutect2, varscan2
- COBL | c.3651C>G p.L1217= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs1329270111, COSV54351821; called by muse, mutect2, varscan2
- COL20A1 | c.288C>T p.F96= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs371649528; called by muse, mutect2, varscan2
- COL6A6 | c.2136C>T p.F712= | Silent (SNP) | VAF 22/119 reads (18%) | catalogued as COSV62030343, COSV62031308; called by muse, mutect2, varscan2
- CORO6 | c.1041C>T p.I347= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV61471369; called by muse, mutect2
- CPSF1 | c.747G>A p.Q249= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV62940130; called by muse, mutect2
- CSF3R | c.1848G>A p.L616= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as COSV58968667; called by muse, mutect2, varscan2
- CYP1B1 | c.84G>A p.S28= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs761360054, COSV53191981; called by muse, mutect2, varscan2
- CYP3A7 | c.9C>G p.L3= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV60482441, COSV60482515; called by muse, mutect2, varscan2
- DALRD3 | c.765A>G p.L255= (on ENST00000341949 / NM_001009996.3; = p.L88= on NM_018114.5) | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV58246231; called by muse, mutect2, varscan2
227 further variants in this file (0 protein-altering or splice-affecting, 205 silent, 22 other) are not listed here.
